Somatic mutation profile of tumor specimen TARGET-10-PARFJM-09A (aliquot TARGET-10-PARFJM-09A-01D) from TARGET case TARGET-10-PARFJM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,293 days).
Specimen TARGET-10-PARFJM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd1d7970-b176-4e64-9847-815fbdd11f5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFJM-10A (Blood Derived Normal), aliquot TARGET-10-PARFJM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d73cfde-489c-4569-b583-1e193232fbcf

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/42 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.3220C>T p.R1074W | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs957375397, COSV57844760; called by muse, mutect2, varscan2
- DMRT3 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as rs537931256; called by muse, mutect2, varscan2
- DNAH5 | c.13054C>T p.R4352W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs530188302, COSV99443626; called by muse, mutect2, varscan2
- EFCAB13 | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs375501418; called by muse, mutect2, varscan2
- KLHL32 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs760800476, COSV65112773; called by muse, mutect2, varscan2
- PLA2G2E | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs147846234, COSV100908831; called by muse, mutect2, varscan2
- PWWP3B | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs771919979, COSV61801553; called by muse, mutect2, varscan2
- SERPINA2 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs567670277; called by muse, mutect2, varscan2
- SIPA1L1 | c.3917G>C p.G1306A | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV100666163; called by muse, mutect2, varscan2
- GFPT1 | c.845G>A p.S282N (on ENST00000357308 / NM_001244710.2; = p.S264N on NM_002056.4) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- TRIL | c.1410G>A p.G470= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs769079754; called by muse, mutect2, varscan2
